Somatic mutation profile of tumor specimen TCGA-34-5929-01A (aliquot TCGA-34-5929-01A-11D-1817-08) from TCGA case TCGA-34-5929, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 79.0 years (28,844 days).
Specimen TCGA-34-5929-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e9a3399-f79b-41a7-9fbf-0a748226eecb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-5929-11A (Solid Tissue Normal), aliquot TCGA-34-5929-11A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/447def7b-d88d-413b-8b0f-90490728980b

The open-access MAF lists 217 somatic variants for this specimen: 162 protein-altering or splice-affecting, 51 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 145, Silent 51, Nonsense Mutation 11, Frame Shift Del 2, Splice Site 2, Translation Start Site 1, 5'UTR 1, Nonstop Mutation 1, 3'Flank 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC17A8 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs121918339, CM083779, COSV60127247; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 41/49 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.745A>G p.K249E | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55965685; called by muse, mutect2, varscan2
- ADH4 | c.410C>A p.T137N | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55502942; called by muse, mutect2, varscan2
- AMER1 | c.428G>T p.C143F | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV57670521; called by muse, mutect2, varscan2
- AMPD3 | c.77C>A p.A26D (on ENST00000396553 / NM_001025389.2; = p.A35D on NM_000480.3) | Missense Mutation (SNP) | VAF 61/102 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67332929; called by muse, mutect2, varscan2
- ANKS1B | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61381185; called by muse, mutect2, varscan2
- ANO2 | c.1303C>A p.P435T (on ENST00000356134 / NM_001278597.3; = p.P439T on NM_001278596.3) | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.731); catalogued as rs201406615, COSV59047141; called by muse, mutect2, varscan2
- APLNR | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 40/125 reads (32%) | catalogued as COSV57244280; called by muse, mutect2, varscan2
- ARHGAP22 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV51003831; called by muse, mutect2, varscan2
- ASCC3 | c.5734G>C p.D1912H | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64978409, COSV64982116; called by muse, mutect2, varscan2
- ATP8A2 | c.2839T>A p.Y947N | Missense Mutation (SNP) | VAF 67/106 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54979572; called by muse, mutect2, varscan2
- B2M | c.215C>G p.S72* | Nonsense Mutation (SNP) | VAF 61/123 reads (50%) | catalogued as COSV62563374, COSV62563575; called by muse, mutect2, varscan2
- BCAT2 | c.726G>T p.Q242H | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV60274429; called by muse, mutect2, varscan2
- BCOR | c.4156G>C p.E1386Q (on ENST00000378444 / NM_001123385.2; = p.E1352Q on NM_017745.6) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); catalogued as COSV60702270, COSV60720638; called by muse, mutect2, varscan2
- BEND2 | c.2116A>T p.S706C | Missense Mutation (SNP) | VAF 131/360 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV66217625; called by muse, mutect2, varscan2
- C12orf42 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV59392061; called by muse, mutect2, varscan2
- C12orf45 | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV55013262; called by muse, mutect2, varscan2
- CCL28 | c.275A>T p.K92I | Missense Mutation (SNP) | VAF 80/278 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV63150363; called by muse, mutect2, varscan2
- CDA | c.182C>A p.P61Q | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.673); catalogued as COSV66752552; called by mutect2, varscan2
- CEP162 | c.3181G>A p.V1061I | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs750195858, COSV57625777; called by muse, mutect2, varscan2
- CFAP74 | c.189G>C p.L63F | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.275); catalogued as COSV54565757, COSV54567361, COSV54575264; called by muse, mutect2, varscan2
- CHD1 | c.1214G>T p.G405V | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV52345474; called by muse, mutect2, varscan2
- CLVS2 | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV51569861; called by muse, mutect2, varscan2
- COL3A1 | c.4275C>A p.S1425R | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV58598076; called by muse, mutect2, varscan2
- CPT1A | c.400G>T p.G134W | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200242711, COSV55762243; called by muse, mutect2, varscan2
- CRB2 | c.3434T>A p.L1145H | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as rs1017481514, COSV63505985; called by muse, mutect2, varscan2
- CUL4B | c.451A>T p.T151S | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV60691711; called by muse, varscan2
- CYB561 | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 64/88 reads (73%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs770920986, COSV62540361, COSV62540374; called by muse, mutect2, varscan2
- DCAF12L2 | c.1052C>A p.T351K | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.368); catalogued as COSV63584578; called by muse, mutect2, varscan2
- DDO | c.115A>C p.T39P | Missense Mutation (SNP) | VAF 75/196 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV64470791; called by muse, mutect2, varscan2
- DLG2 | c.167A>T p.H56L | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as COSV65882759; called by muse, mutect2, varscan2
- DMD | c.5935G>A p.E1979K | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.053); catalogued as COSV63787255; called by muse, mutect2, varscan2
- DMTN | c.934G>C p.E312Q | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.177); catalogued as rs1253569249, COSV56113060; called by muse, mutect2, varscan2
- DNASE1L1 | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV50011456; called by muse, mutect2, varscan2
- ERGIC2 | c.746A>G p.Y249C | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64113636; called by muse, mutect2, varscan2
- ERICH5 | c.599C>G p.A200G | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as rs746855901, COSV59317527; called by muse, mutect2, varscan2
- EYA4 | c.619G>C p.G207R | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62062522; called by muse, mutect2, varscan2
- FAM71B | c.599G>T p.S200I | Missense Mutation (SNP) | VAF 144/268 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as COSV57231888; called by muse, mutect2, varscan2
- FAP | c.135G>T p.K45N | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV51868517; called by muse, mutect2, varscan2
- FBXL18 | c.1430C>T p.S477F | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.103); catalogued as COSV66107953; called by muse, mutect2, varscan2
- FLRT2 | c.38C>A p.A13D | Missense Mutation (SNP) | VAF 56/92 reads (61%) | SIFT tolerated (0.24); PolyPhen benign (0.137); catalogued as COSV58151640; called by muse, mutect2, varscan2
- FN1 | c.4663G>C p.D1555H | Missense Mutation (SNP) | VAF 76/208 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV60566036; called by muse, mutect2, varscan2
- FREM1 | c.1601A>T p.E534V | Missense Mutation (SNP) | VAF 61/111 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1235730297, COSV66531743; called by muse, mutect2, varscan2
- FSIP2 | c.20373C>G p.H6791Q | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58102530; called by muse, mutect2, varscan2
- FYB1 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60957666; called by muse, mutect2, varscan2
- GADD45B | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.057); catalogued as COSV53126897; called by muse, mutect2, varscan2
- GPM6A | c.557G>C p.G186A | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV54564075; called by muse, mutect2, varscan2
- GRIN2D | c.2570G>T p.G857V | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV53521117; called by muse, mutect2, varscan2
- GXYLT1 | c.773G>T p.R258L | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs76555438, COSV55138876; called by muse, mutect2, varscan2
- H2AC1 | c.35G>C p.R12P | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.473); catalogued as COSV51238948; called by muse, mutect2, varscan2
- HERPUD2 | c.1220G>T p.*407Lext*18 | Nonstop Mutation (SNP) | VAF 48/144 reads (33%) | catalogued as COSV60945218; called by muse, mutect2, varscan2
- ICE2 | c.779A>G p.H260R | Missense Mutation (SNP) | VAF 32/270 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as COSV55034498; called by muse, mutect2, varscan2
- IDS | c.77C>G p.S26C | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.125); catalogued as rs1557340575, COSV61715225; called by muse, mutect2, varscan2
- IGFBP7 | c.533A>G p.Y178C | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV55277580; called by muse, varscan2
- IGSF3 | c.298G>T p.G100W | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59600116; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.523G>C p.E175Q (on ENST00000485419 / NM_001197113.1; = p.E99Q on NM_014575.3) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.426); catalogued as COSV100540971, COSV61862943; called by muse, mutect2, varscan2
- IRX4 | c.1262C>G p.S421C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as rs760757837, COSV51475421; called by muse, mutect2, varscan2
- ITFG2 | c.422G>C p.R141P | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as COSV57391422, COSV99958159; called by muse, mutect2, varscan2
- JPH2 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1344351300, COSV65904578; called by muse, mutect2, varscan2
- KCNH1 | c.2927C>A p.P976Q (on ENST00000271751 / NM_172362.3; = p.P949Q on NM_002238.4) | Missense Mutation (SNP) | VAF 79/255 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV55077701; called by muse, mutect2, varscan2
- KIAA0319L | c.2326G>A p.D776N | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV57842004, COSV57851877; called by muse, mutect2, varscan2
- KIAA0895 | c.1072G>T p.E358* (on ENST00000297063 / NM_001100425.2; = p.E307* on NM_015314.3) | Nonsense Mutation (SNP) | VAF 30/112 reads (27%) | catalogued as COSV51714697; called by muse, mutect2, varscan2
- KLC4 | c.1625C>G p.S542C | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.343); catalogued as COSV52440085; called by muse, mutect2, varscan2
- KLF4 | c.395C>G p.S132C | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.646); catalogued as COSV65929689; called by mutect2, varscan2
- KLHL14 | c.1522C>A p.R508S | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV63836027; called by muse, mutect2, varscan2
- LRRC7 | c.727C>A p.Q243K (on ENST00000651989 / NM_001370785.2; = p.Q210K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/273 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as COSV50533421, COSV50652759, COSV99226771; called by muse, mutect2, varscan2
- LSM14A | c.1137-1G>C p.X379_splice | Splice Site (SNP) | VAF 19/40 reads (48%) | catalogued as COSV70885793; called by muse, mutect2, varscan2
- LSM4 | c.159C>G p.F53L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV53254256; called by muse, mutect2, varscan2
- LTBP1 | c.2518G>A p.V840I (on ENST00000404816 / NM_206943.4; = p.V514I on NM_000627.4) | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV100616968, COSV63199190; called by muse, mutect2, varscan2
- MAG | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.101); catalogued as COSV62703403; called by muse, mutect2, varscan2
- MAGEB2 | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV66780260, COSV66782181; called by muse, mutect2, varscan2
- MCM6 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.173); catalogued as COSV51470104; called by muse, mutect2, varscan2
- MED23 | c.3557A>T p.Y1186F | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.506); catalogued as COSV63438045; called by muse, mutect2, varscan2
- MMP16 | c.634C>A p.P212T | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54193466; called by muse, mutect2, varscan2
- MUC5B | c.11767A>T p.T3923S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.048); catalogued as COSV71596538; called by muse, varscan2
- MYBL1 | c.2230A>G p.S744G | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV72919277; called by muse, mutect2, varscan2
- MYO1B | c.1306C>T p.H436Y | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as COSV58439296; called by muse, mutect2, varscan2
- MYOM1 | c.206C>A p.S69Y | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55302737; called by muse, mutect2, varscan2
- NCAM1 | c.1750G>A p.V584I (on ENST00000316851 / NM_181351.5; = p.V574I on NM_000615.7) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.049); catalogued as rs375525449; called by muse, mutect2, varscan2
- NIPAL4 | c.232C>T p.L78F | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs1200241228, COSV61731377; called by muse, mutect2, varscan2
- NSD1 | c.6022G>A p.D2008N | Missense Mutation (SNP) | VAF 57/98 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61786322; called by muse, mutect2, varscan2
- NYAP2 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.267); catalogued as COSV56001420; called by muse, mutect2
- OBSCN | c.22533C>G p.I7511M | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100806155, COSV63625190; called by muse, mutect2, varscan2
- OR2A5 | c.388C>A p.L130M | Missense Mutation (SNP) | VAF 95/238 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV68739254; called by muse, mutect2, varscan2
- OR2K2 | c.287C>G p.S96C (on ENST00000374428; = p.S67C on NM_205859.2) | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV57018680; called by muse, mutect2, varscan2
- OR2T34 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 22/111 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.107); catalogued as COSV60900605, COSV60902236; called by muse, mutect2, varscan2
- OR4M1 | c.553G>T p.V185F | Missense Mutation (SNP) | VAF 90/168 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as rs776878624, COSV60064001; called by muse, mutect2, varscan2
- OR6T1 | c.764C>A p.S255Y | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV58305873, COSV58308619; called by muse, mutect2, varscan2
- P4HA2 | c.148G>T p.V50L | Missense Mutation (SNP) | VAF 65/109 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV51333291; called by muse, mutect2, varscan2
- PCDH11X | c.318C>A p.C106* | Nonsense Mutation (SNP) | VAF 70/253 reads (28%) | catalogued as COSV53500388, COSV53512605; called by muse, mutect2, varscan2
- PCDH11X | c.319T>A p.F107I | Missense Mutation (SNP) | VAF 68/251 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV53512638; called by muse, mutect2, varscan2
- PCDH11X | c.3247C>T p.H1083Y | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.78); catalogued as COSV100014354, COSV53512666; called by muse, mutect2, varscan2
- PHKA1 | c.2971G>A p.A991T | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.138); catalogued as COSV59812702; called by muse, mutect2, varscan2
- PHKA2 | c.3143C>A p.T1048K | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.87); PolyPhen benign (0.006); catalogued as COSV66056871; called by muse, mutect2, varscan2
- PKHD1 | c.2633C>G p.A878G | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV61897881; called by muse, mutect2, varscan2
- PKHD1 | c.582A>G p.I194M | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV61897893; called by muse, mutect2, varscan2
- PLCE1 | c.1388C>T p.S463L | Missense Mutation (SNP) | VAF 76/126 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.122); catalogued as rs763640206, COSV53375637; called by muse, mutect2, varscan2
- PLCL1 | c.1919C>G p.S640* | Nonsense Mutation (SNP) | VAF 26/58 reads (45%) | catalogued as COSV70883685; called by muse, mutect2, varscan2
- POLA1 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66891527; called by muse, mutect2, varscan2
- PRELID1 | c.594G>C p.E198D | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV57464333; called by muse, mutect2, varscan2
- PRODH2 | c.633G>A p.M211I (on ENST00000301175; = p.M135I on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV56562669; called by muse, mutect2, varscan2
- PTPN18 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as rs199586116, COSV51560967; called by muse, mutect2, varscan2
- PTPRD | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV100644866, COSV61987867; called by muse, mutect2, varscan2
- PTPRZ1 | c.4475C>T p.S1492L | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV66447244; called by muse, mutect2, varscan2
- RAB36 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV53272824; called by muse, mutect2, varscan2
- RASGEF1A | c.1357G>A p.V453I | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1375844367, COSV65666584; called by muse, mutect2, varscan2
- RDX | c.737G>A p.R246K | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.799); catalogued as COSV58197036; called by muse, mutect2, varscan2
- REG3A | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as COSV59412199, COSV59412447; called by muse, mutect2, varscan2
- RET | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as CM001780, COSV60710731; called by muse, mutect2, varscan2
- RPAP1 | c.2998G>A p.E1000K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV58543081; called by muse, mutect2, varscan2
- RSBN1 | c.92G>C p.R31P | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV54735971, COSV99793357; called by muse, mutect2, varscan2
- RYR2 | c.11228C>A p.T3743K | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.53); catalogued as COSV63720097; called by muse, mutect2, varscan2
- SCLT1 | c.1046A>T p.Q349L | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55414005; called by muse, mutect2, varscan2
- SCN9A | c.3677T>A p.L1226Q (on ENST00000303354; = p.L1215Q on NM_002977.3) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57627893; called by muse, mutect2, varscan2
- SGSM1 | c.699G>C p.M233I | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.519); catalogued as COSV68514340; called by muse, mutect2, varscan2
- SLC17A2 | c.604C>A p.L202I | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.145); catalogued as COSV55350691; called by muse, mutect2, varscan2
- SLC17A4 | c.1169C>A p.S390Y | Missense Mutation (SNP) | VAF 86/201 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.316); catalogued as COSV64957513; called by muse, mutect2, varscan2
- SLC2A2 | c.1280T>C p.F427S | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58588980; called by muse, mutect2, varscan2
- SLC7A3 | c.466G>T p.V156L | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.089); catalogued as COSV53226524, COSV53229811; called by muse, mutect2, varscan2
- SORCS1 | c.2223G>T p.Q741H | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); catalogued as COSV53912265; called by muse, mutect2
- SPTA1 | c.2044C>A p.Q682K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV63761148; called by muse, mutect2, varscan2
- SPTBN2 | c.1811A>G p.Y604C | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1007920541, COSV59462718; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2477G>T p.G826V | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100561608, COSV100561793; called by muse, mutect2, varscan2
- SYP | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.297); catalogued as COSV54297281; called by muse, mutect2, varscan2
- TAF1 | c.1781A>C p.Q594P (on ENST00000373790 / NM_138923.4; = p.Q615P on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.53); catalogued as COSV52128007; called by muse, mutect2, varscan2
- TAS2R19 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 72/213 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.192); catalogued as COSV101114721; called by muse, varscan2
- TCEAL6 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 101/233 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs368492884, COSV65653988; called by muse, mutect2, varscan2
- TCN1 | c.418C>A p.P140T | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57255009; called by muse, varscan2
- TEKT4 | c.239C>A p.A80E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV54629206; called by muse, mutect2
- TENM2 | c.6007G>A p.D2003N (on ENST00000518659 / NM_001122679.2; = p.D1764N on NM_001080428.3) | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.928); catalogued as COSV69144089; called by muse, mutect2, varscan2
- TLL1 | c.847G>C p.E283Q | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV50282589, COSV50336273, COSV99287092; called by muse, mutect2, varscan2
- TLR4 | c.558G>C p.K186N (on ENST00000355622 / NM_138554.5; = p.K146N on NM_003266.4) | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as rs199943556, COSV62924480; called by muse, mutect2, varscan2
- TMEM132D | c.1658G>T p.G553V | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV101242522, COSV67160356, COSV67163073; called by muse, mutect2, varscan2
- TMEM237 | c.241C>T p.Q81* (on ENST00000409883 / NM_001044385.3; = p.Q73* on NM_152388.4) | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV53807220; called by muse, mutect2, varscan2
- TMPRSS9 | c.1247C>G p.S416C (on ENST00000648592; = p.S382C on NM_182973.2) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV60232149; called by muse, mutect2, varscan2
- TPO | c.2057T>C p.L686P | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61112885; called by muse, mutect2, varscan2
- TRERF1 | c.922C>T p.Q308* | Nonsense Mutation (SNP) | VAF 32/84 reads (38%) | catalogued as COSV100550616; called by mutect2, varscan2
- TRIM63 | c.401G>C p.C134S | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65329660; called by muse, mutect2, varscan2
- TRIP12 | c.5113G>A p.A1705T | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52274079; called by muse, mutect2, varscan2
- TSHZ2 | c.970G>T p.V324F | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as rs138844500, COSV61592313; called by muse, mutect2, varscan2
- TTN | c.44842G>C p.E14948Q (on ENST00000591111; = p.E7524Q on NM_003319.4) | Missense Mutation (SNP) | VAF 28/79 reads (35%) | PolyPhen probably damaging (0.997); catalogued as COSV60403823; called by muse, mutect2, varscan2
- TTN | c.10621G>A p.V3541M (on ENST00000591111; = p.V3495M on NM_003319.4) | Missense Mutation (SNP) | VAF 61/197 reads (31%) | catalogued as COSV60403868; called by muse, mutect2, varscan2
- USP24 | c.2509G>T p.E837* | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | catalogued as COSV53780601; called by muse, mutect2, varscan2
- USP9X | c.4272G>C p.E1424D | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV61076426; called by muse, mutect2, varscan2
- USP9X | c.4987G>C p.V1663L | Missense Mutation (SNP) | VAF 78/216 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as COSV61076438; called by muse, mutect2, varscan2
- UXS1 | c.305C>G p.S102C | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51683058; called by muse, mutect2, varscan2
- VGF | c.668T>G p.L223R | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.26); catalogued as COSV50802858; called by muse, mutect2, varscan2
- VPS13B | c.6832G>A p.E2278K | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.039); catalogued as COSV62160399; called by muse, mutect2, varscan2
- WDR17 | c.1172G>A p.G391E | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781208891, COSV54585955; called by muse, mutect2, varscan2
- WDR44 | c.1497G>T p.Q499H | Missense Mutation (SNP) | VAF 76/200 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.085); catalogued as rs1326631223, COSV54170380; called by muse, mutect2, varscan2
- ZBTB48 | c.773C>G p.S258* | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | catalogued as COSV59841031; called by muse, mutect2, varscan2
- ZFHX4 | c.8057C>G p.A2686G | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV51500968; called by muse, varscan2
- ZFYVE26 | c.4255G>T p.E1419* | Nonsense Mutation (SNP) | VAF 71/116 reads (61%) | catalogued as COSV100720253, COSV61334406; called by muse, mutect2, varscan2
- ZNF236 | c.193-2A>G p.X65_splice | Splice Site (SNP) | VAF 16/62 reads (26%) | catalogued as COSV53499926; called by muse, varscan2
- ZNF431 | c.1301G>T p.G434V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60675905; called by muse, mutect2, varscan2
- ZNF667 | c.1539C>G p.H513Q | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.746); catalogued as rs912382330, COSV52640390; called by muse, mutect2, varscan2
- ZNF708 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 15/62 reads (24%) | catalogued as COSV63609074; called by muse, mutect2, varscan2
- BPIFC | c.1079T>C p.I360T | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ITM2A | c.421del p.I141Lfs*9 | Frame Shift Del (DEL) | VAF 22/69 reads (32%) | called by mutect2, pindel, varscan2
- PDE4DIP | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- PZP | c.779del p.P260Qfs*6 | Frame Shift Del (DEL) | VAF 37/125 reads (30%) | called by mutect2, varscan2
- ADAMTS1 | c.1056A>G p.T352= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV53171201, COSV53174153; called by muse, mutect2, varscan2
- ADGRB3 | c.2289C>T p.G763= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs761752486, COSV65388679, COSV65393176; called by muse, mutect2, varscan2
- ADGRF5 | c.2784C>T p.V928= | Silent (SNP) | VAF 71/173 reads (41%) | catalogued as rs369593357; called by muse, mutect2, varscan2
- AL645922.1 | c.3117C>A p.I1039= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as COSV54962983; called by muse, mutect2, varscan2
- ANKIB1 | c.2586A>G p.L862= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as COSV56066878; called by muse, mutect2, varscan2
- APEH | c.585G>A p.K195= | Silent (SNP) | VAF 28/45 reads (62%) | catalogued as rs1164109767, COSV56529671; called by muse, mutect2, varscan2
- ATXN3L | c.945A>G p.T315= | Silent (SNP) | VAF 107/258 reads (41%) | catalogued as COSV66076353; called by muse, mutect2, varscan2
- CARD14 | c.2607G>A p.Q869= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV58340880; called by muse, mutect2, varscan2
- CFAP65 | c.42G>A p.Q14= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as rs372741687; called by muse, mutect2, varscan2
- CHD6 | c.6861G>T p.R2287= | Silent (SNP) | VAF 65/179 reads (36%) | catalogued as COSV64695496; called by muse, mutect2, varscan2
- DLGAP2 | c.1905C>A p.T635= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV70104360; called by muse, mutect2, varscan2
- EGFLAM | c.2235G>T p.V745= | Silent (SNP) | VAF 36/146 reads (25%) | catalogued as COSV59320305; called by muse, mutect2, varscan2
- FOXP2 | c.1350A>T p.P450= | Silent (SNP) | VAF 61/147 reads (41%) | catalogued as COSV63495342; called by muse, mutect2, varscan2
- HEG1 | c.876G>A p.R292= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV60766240; called by muse, mutect2, varscan2
- IRS4 | c.3255A>G p.P1085= | Silent (SNP) | VAF 72/216 reads (33%) | catalogued as COSV64536454; called by muse, mutect2, varscan2
- ITIH6 | c.1860C>A p.T620= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs772998627, COSV54495814; called by muse, mutect2, varscan2
- KIF16B | c.3618C>T p.V1206= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as COSV61716624; called by muse, mutect2, varscan2
- LCA5 | c.87G>A p.T29= | Silent (SNP) | VAF 101/275 reads (37%) | catalogued as rs369647371; called by muse, mutect2, varscan2
- LRP4 | c.2790T>C p.A930= | Silent (SNP) | VAF 51/196 reads (26%) | catalogued as COSV66139211; called by muse, mutect2, varscan2
- MAP3K15 | c.2568G>A p.E856= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV58840347; called by muse, mutect2, varscan2
- MR1 | c.261G>T p.L87= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV51582449; called by muse, mutect2, varscan2
- MUC4 | c.15732C>G p.V5244= (on ENST00000463781 / NM_018406.7; = p.V1008= on NM_004532.6) | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as COSV57806544; called by muse, mutect2, varscan2
- NEU2 | c.1077C>T p.Y359= | Silent (SNP) | VAF 95/280 reads (34%) | catalogued as rs201865338, COSV52093716; called by muse, mutect2, varscan2
- NNT | c.1581G>C p.L527= | Silent (SNP) | VAF 110/459 reads (24%) | catalogued as COSV52923652, COSV52930486; called by muse, mutect2, varscan2
- OR10G4 | c.423C>A p.A141= | Silent (SNP) | VAF 83/332 reads (25%) | catalogued as COSV57979394; called by muse, mutect2, varscan2
- OR2B11 | c.400C>T p.L134= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as COSV59511873; called by muse, mutect2, varscan2
- OR2T35 | c.660C>T p.H220= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as COSV58087622; called by muse, mutect2, varscan2
- PAGE2B | c.15G>C p.V5= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV66611698; called by muse, mutect2, varscan2
- PDHA1 | c.507G>T p.A169= | Silent (SNP) | VAF 45/118 reads (38%) | catalogued as COSV63329246; called by muse, mutect2, varscan2
- PGD | c.195G>A p.L65= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as COSV54623577; called by muse, mutect2, varscan2
- PKHD1 | c.11739C>A p.R3913= | Silent (SNP) | VAF 67/179 reads (37%) | catalogued as COSV64402284; called by muse, mutect2, varscan2
- PKHD1L1 | c.7119C>A p.L2373= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV65755542; called by muse, mutect2, varscan2
- PLEKHG2 | c.2514A>G p.A838= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV52691067; called by muse, mutect2
- PPARD | c.846C>G p.L282= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV61101801; called by muse, mutect2, varscan2
- PRAMEF6 | c.876G>A p.L292= | Silent (SNP) | VAF 30/378 reads (8%) | catalogued as COSV100755853, COSV99049817; called by muse, varscan2
- RAB12 | c.237C>T p.F79= | Silent (SNP) | VAF 54/188 reads (29%) | catalogued as COSV61399432; called by muse, mutect2, varscan2
- RP1L1 | c.3549C>T p.D1183= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs1342171016, COSV66761298; called by muse, mutect2, varscan2
- RYR3 | c.9006C>A p.S3002= (on ENST00000389232; = p.S3003= on NM_001036.6) | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV66811068; called by muse, mutect2, varscan2
- SALL1 | c.1650T>A p.T550= | Silent (SNP) | VAF 44/75 reads (59%) | catalogued as COSV51765517; called by muse, mutect2, varscan2
- SEMA6D | c.2059C>A p.R687= (on ENST00000316364 / NM_153618.2; = p.R625= on NM_020858.2) | Silent (SNP) | VAF 110/174 reads (63%) | catalogued as COSV60372185, COSV60385429; called by muse, mutect2, varscan2
- SORBS3 | c.357C>T p.V119= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV53555333; called by muse, mutect2, varscan2
- SPATA31A3 | c.2286C>A p.P762= | Silent (SNP) | VAF 5/8 reads (63%) | called by mutect2, varscan2
- SPTA1 | c.2043C>A p.T681= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV63760948; called by muse, mutect2, varscan2
- TAAR5 | c.468G>T p.L156= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as COSV57800026; called by muse, mutect2, varscan2
- TMEM63A | c.105G>T p.S35= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV64764336; called by muse, mutect2, varscan2
- TRMT2B | c.1428C>G p.G476= | Silent (SNP) | VAF 53/120 reads (44%) | catalogued as COSV58621447; called by muse, mutect2, varscan2
- TSPAN7 | c.729C>A p.A243= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV54534948; called by muse, mutect2, varscan2
- WNT16 | c.222C>G p.A74= (on ENST00000222462 / NM_057168.2; = p.A64= on NM_016087.2) | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV55978067; called by muse, mutect2, varscan2
- ZFAT | c.3330G>T p.A1110= | Silent (SNP) | VAF 85/274 reads (31%) | catalogued as rs367952040, COSV64748840; called by muse, mutect2, varscan2
- ZFHX4 | c.8064G>T p.S2688= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as COSV51472767, COSV51500973; called by muse, varscan2
- ZNF280A | c.159A>G p.S53= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as COSV57482686; called by muse, mutect2, varscan2
- AL136439.1 | chr13:27665825 G>A | 3'Flank (SNP) | VAF 23/49 reads (47%) | catalogued as COSV68800208; called by muse, mutect2, varscan2
- PECR | c.-1G>T | 5'UTR (SNP) | VAF 10/40 reads (25%) | catalogued as rs369516253; called by muse, mutect2, varscan2
- XIST | n.11217A>C | RNA (SNP) | VAF 56/189 reads (30%) | called by muse, mutect2, varscan2
- Z82195.2 | n.416-19562C>T | Intron (SNP) | VAF 28/72 reads (39%) | catalogued as rs1369342786; called by muse, mutect2, varscan2
